CCDI case PBCPXT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2dfd8d37-39a0-4b2e-aecf-6c7df60be6ff

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.8 years (1,764 days).

Biospecimens (3 samples)
- Sample 0DX4EU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX4FH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX4FT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
